Somatic mutation profile of tumor specimen 0DSEL4 from CCDI case PBCHXF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,241 days).
Specimen 0DSEL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6045a439-8ab0-46b8-a891-32f6c2a54e0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEKV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea69ea61-b75d-4ab4-b137-ddf65001f5cc

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Nonsense Mutation 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 152/162 reads (94%) | catalogued as rs1131690986, CM971257, COSV59462168; ClinVar: pathogenic; called by muse, varscan2
- OR5D16 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 326/709 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs779891030; called by muse, varscan2
- NPDC1 | c.543C>T p.D181= | Silent (SNP) | VAF 220/262 reads (84%) | catalogued as rs768831053, COSV99041697; called by muse, varscan2
- SOX2 | c.375C>T p.Y125= | Silent (SNP) | VAF 200/466 reads (43%) | catalogued as rs781054227; called by muse, varscan2
- LZTR1 | c.*10_*38del | 3'UTR (DEL) | VAF 107/316 reads (34%) | catalogued as rs1362668052; called by pindel, varscan2
